HCMI case HCM-BROD-0225-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb71a9ce-2934-40a4-a99a-b8e5b5491a55

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 42.8 years (15,646 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3a; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,876 days (7.9 years); Days to treatment end: 2,917 days (8.0 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 50.6 years (18,482 days); Days to diagnosis: 2,836 days (7.8 years).
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 9.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Not Otherwise Specified; Treatment intent type: Maintenance Therapy; Days to treatment start: 1,420 days (3.9 years); Days to treatment end: 2,786 days (7.6 years); Treatment outcome: Stable Disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 3,585.

Molecular and laboratory tests
- BRAF (IHC): Negative; Amino-acid change: V600E.
- BRAF mutation, nos: Negative.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 113 kg; Height: 193 cm; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-BROD-0225-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0225-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
- Sample HCM-BROD-0225-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
